Gene-level copy-number profile of tumor specimen TCGA-D8-A13Z-01A from TCGA case TCGA-D8-A13Z, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.9 years (18,942 days).
Specimen TCGA-D8-A13Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a0230b81-eee6-4c5f-b6de-cb9215dbda5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A13Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/92168a21-844c-46ad-89fd-79e17f87fa37

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,155; copy number 2: 5,318; copy number 3: 17,447; copy number 4: 12,642; copy number 5: 11,109; copy number 6: 3,874; copy number 7: 3,507; copy number 8: 2,499; copy number 9: 797; copy number 10: 320; copy number 11: 149; copy number 12: 173; copy number 13: 190; copy number 14: 289; copy number 15: 5; copy number 18: 36; copy number 19: 67; copy number 22: 106; copy number 24: 16; copy number 28: 8; copy number 29: 80; copy number 35: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A13Z-01A-11D-A111-01): tumor purity 0.38, ploidy 4.31, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 8,097 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,353,986–121,580,524, 167 genes, copy number 7 (broad region; genes not listed).
- chr1:160,995,211–181,238,604, 442 genes, copy number 9–11 (broad region; genes not listed).
- chr1:183,248,237–192,185,815, 108 genes, copy number 7–11 (broad region; genes not listed).
- chr1:192,246,708–192,367,285, 3 genes, copy number 7: AL513175.1, AL513175.2, RGS21.
- chr1:206,507,531–206,589,448, 1 gene, copy number 9 (within-gene range 6–9): RASSF5.
- chr1:206,541,758–213,988,508, 163 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr1:225,777,813–248,919,946, 590 genes, copy number 7 (broad region; genes not listed).
- chr2:38,814–88,750,929, 1,523 genes, copy number 8 (broad region; genes not listed).
- chr4:146,580,048–148,072,776, 23 genes, copy number 7: RNU1-44P, POU4F2, TTC29, AC092435.2, AC092435.1, AC092435.3, AC092435.4, AC097450.1, MIR548G, AC010683.1, PRMT5P1, EDNRA, AC093908.1, GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1.
- chr4:155,173,716–155,381,694, 1 gene, copy number 7 (within-gene range 3–7): AC097467.3.
- chr4:155,286,162–174,001,488, 232 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr5:157,565,964–157,859,145, 11 genes, copy number 8: AC106801.1, RNU6-390P, AC008694.2, SOX30, C5orf52, AC008694.1, THG1L, LSM11, AC026407.1, CLINT1, RNU6-260P.
- chr6:7,881,522–8,064,364, 1 gene, copy number 14 (within-gene range 6–14): BLOC1S5-TXNDC5.
- chr6:7,986,537–10,211,608, 13 genes, copy number 8–14 (within-gene range 6–14): PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1, AL136226.1.
- chr6:35,213,956–97,140,754, 900 genes, copy number 7–8 (broad region; genes not listed).
- chr6:105,904,373–149,112,672, 643 genes, copy number 7–14 (broad region; genes not listed).
- chr6:156,776,020–157,210,779, 1 gene, copy number 8 (within-gene range 6–8): ARID1B.
- chr6:156,976,294–159,401,147, 53 genes, copy number 8: AL162578.1, AL049820.1, TMEM242, LDHAL6FP, AL390955.2, AL390955.1, AL117344.1, AL117344.2, ZDHHC14, MIR3692, SNX9, AL391863.2, AL391863.1, SNX9-AS1, HSPE1P26, RNU6-786P, SYNJ2, AL139330.1, SYNJ2-IT1, SERAC1, GTF2H5, TULP4, SRP72P2, AL360169.2, AL360169.3, AL360169.1, RN7SL173P, CACYBPP3, TMEM181, TATDN2P2, MIR7161, DYNLT1, SYTL3, AMZ2P2, MIR3918, EZR, EZR-AS1, OSTCP1, AL627422.2, C6orf99, AL627422.1, RNU6-293P, RSPH3, AL035530.2, TAGAP, AL035530.1, AL356417.3, AL356417.1, AL356417.2, FNDC1, FNDC1-IT1, AL357832.1, LINC02529.
- chr6:163,671,577–166,906,451, 44 genes, copy number 12–18 (within-gene range 6–18): AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1, AL136100.1, C6orf118, PDE10A, RNA5SP226, RNU6-730P, AL590302.2, AL590302.1, LINC00602, GAPDHP72, AL627443.3, AL627443.1, AL627443.2, TBXT, LNCDAT, RNU6-153P, AL121956.6, AL121956.1, GNG5P1, AL121956.5, PRR18, AL121956.7, SFT2D1, HNRNPA1P49, AL022069.3, MPC1, AL022069.1, AL022069.2, RPS6KA2, RPS6KA2-IT1, MIR1913, RAMACL, AL023775.2.
- chr6:169,788,790–170,738,536, 26 genes, copy number 8 (within-gene range 6–8): LINC00242, LINC00574, AL049612.1, AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr8:36,378,069–38,409,527, 55 genes, copy number 12 (within-gene range 1–12): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2.
- chr8:38,408,048–38,426,096, 2 genes, copy number 12: AC087623.3, AC087623.1.
- chr10:44,712–9,309,772, 172 genes, copy number 7 (broad region; genes not listed).
- chr10:14,074,284–16,817,463, 41 genes, copy number 7 (within-gene range 6–7): AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265, FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1, FAM171A1, AL607028.1, ITGA8, MINDY3, AL358033.1, FTLP19, RNU6-1075P, LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1.
- chr10:52,230,398–67,696,195, 117 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr10:68,896,920–71,077,810, 58 genes, copy number 7: AL359844.1, DDX50, RNU6-571P, DDX21, KIFBP, MED28P1, ACTBP14, SRGN, Metazoa_SRP, VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26, COL13A1, LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1, ADAMTS14, TBATA, RPS26P40, SGPL1, PCBD1, AC073176.2, AC073176.1, LINC02622.
- chr10:123,913,574–133,761,125, 178 genes, copy number 8–9 (broad region; genes not listed).
- chr12:66,767–46,876,784, 974 genes, copy number 7–24 (within-gene range 3–24) (broad region; genes not listed).
- chr14:18,333,726–52,010,694, 871 genes, copy number 7–35 (broad region; genes not listed).
- chr14:54,396,849–57,994,525, 71 genes, copy number 9–12 (broad region; genes not listed).
- chr19:38,899,700–41,640,602, 162 genes, copy number 8 (broad region; genes not listed).
- chr19:43,278,933–44,401,608, 63 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr20:60,087,826–64,313,132, 153 genes, copy number 7–22 (within-gene range 5–22) (broad region; genes not listed).
- chr21:15,050,189–30,643,136, 235 genes, copy number 7–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
